Gene-level copy-number profile of tumor specimen RC-B6SE-TTP1-A from RC case RC-B6SE, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 58.3 years (21,302 days).
Specimen RC-B6SE-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 712ec635-3fbe-4ec3-9758-7597ce444eb1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6SE-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/43bfcb99-fc87-4ea8-af96-e0d4255d1618

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 344; copy number 1: 953; copy number 2: 52,655; copy number 3: 4,438.

Homozygous deletions (total copy number 0; autosomes only): 343 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:69,433,255–69,435,409, 1 gene: LINC01758.
- chr1:73,635,216–73,715,214, 1 gene: LINC02238.
- chr1:74,198,212–74,234,086, 1 gene (within-gene range 0–2): FPGT.
- chr1:194,488,103–194,488,205, 1 gene: RNU6-983P.
- chr2:89,297,264–89,600,680, 5 genes: IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:140,234,737–140,234,923, 1 gene (within-gene range 0–2): AC092156.1.
- chr2:155,089,439–155,089,538, 1 gene: RNU6-1001P.
- chr2:185,652,374–185,800,151, 1 gene (within-gene range 0–2): FSIP2-AS1.
- chr2:185,738,804–185,833,290, 1 gene (within-gene range 0–2): FSIP2.
- chr3:28,315,003–28,349,050, 1 gene (within-gene range 0–2): AZI2.
- chr5:100,153,672–100,153,779, 1 gene: RNU6-1119P.
- chr5:111,091,716–111,130,502, 1 gene (within-gene range 0–2): WDR36.
- chr5:125,966,777–125,968,085, 1 gene: RPSAP37.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr6:93,811,825–93,813,036, 1 gene: AL356094.1.
- chr6:115,633,540–115,643,916, 1 gene: LINC02534.
- chr7:9,621,764–9,769,513, 1 gene (within-gene range 0–2): AC060834.2.
- chr7:38,256,337–38,311,808, 9 genes (within-gene range 0–2): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr8:78,398,515–78,398,622, 1 gene: RNU6-1220P.
- chr8:82,979,411–82,979,886, 1 gene: AC105031.1.
- chr8:91,157,285–91,158,748, 1 gene (within-gene range 0–2): CPP.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr10:54,452,423–54,452,511, 1 gene (within-gene range 0–2): RNU6-687P.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr12:28,505,394–28,505,528, 1 gene (within-gene range 0–2): RNA5SP355.
- chr12:33,576,095–33,576,200, 1 gene: RNU6-400P.
- chr12:60,341,824–60,341,941, 1 gene: Y_RNA.
- chr12:87,041,916–87,042,423, 1 gene: AC079597.1.
- chr14:21,918,188–22,552,156, 112 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,639,559–106,803,233, 179 genes (broad region; genes not listed).
- chr21:9,325,013–9,914,846, 12 genes: CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 953. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
